Somatic mutation profile of tumor specimen TCGA-DK-AA6L-01A (aliquot TCGA-DK-AA6L-01A-11D-A391-08) from TCGA case TCGA-DK-AA6L, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 48.3 years (17,635 days).
Specimen TCGA-DK-AA6L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5660978-a064-44aa-bfdf-f2448b4643d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA6L-10A (Blood Derived Normal), aliquot TCGA-DK-AA6L-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca7e11b5-39c8-4cee-9834-c073d5ecdb8a

The open-access MAF lists 444 somatic variants for this specimen: 333 protein-altering or splice-affecting, 102 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 288, Silent 102, Nonsense Mutation 23, Frame Shift Del 9, In Frame Del 6, Splice Site 4, Intron 4, 5'UTR 3, Splice Region 2, 3'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 44/187 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABCC5 | c.4247C>G p.S1416C | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV55597149; called by muse, mutect2
- ACOT12 | c.766C>G p.Q256E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as COSV56895613, COSV56896007, COSV56898607; called by muse, mutect2, varscan2
- ADAMTSL3 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149710156, COSV99721647; called by muse, mutect2, varscan2
- ADCY8 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53930637; called by muse, mutect2, varscan2
- AGL | c.4367G>T p.G1456V | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54059523; called by muse, mutect2
- AHNAK | c.3055G>C p.D1019H | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57233391; called by muse, mutect2, varscan2
- AHNAK2 | c.10914C>G p.F3638L | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV100317549, COSV60932693; called by muse, mutect2, varscan2
- AKAP6 | c.4540C>T p.Q1514* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | catalogued as COSV99805034; called by muse, mutect2, varscan2
- AKT1 | c.1000G>T p.G334W | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62574650, COSV62576438; called by muse, mutect2, varscan2
- ALDH1L1 | c.555G>C p.E185D | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.001); catalogued as COSV56419954; called by muse, mutect2, varscan2
- ALS2 | c.4661C>T p.S1554L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51893538, COSV51893561; called by muse, varscan2
- AMY2A | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 40/216 reads (19%) | catalogued as rs1346316890, COSV101340685; called by muse, mutect2, varscan2
- ANAPC2 | c.2306C>T p.S769L | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs1171681598, COSV100119259; called by muse, mutect2, varscan2
- ANAPC2 | c.2213C>G p.S738C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60572637; called by muse, mutect2, varscan2
- ANK2 | c.4657G>A p.E1553K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52147412, COSV52157115; called by muse, mutect2, varscan2
- APBB1IP | c.807C>A p.N269K | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV63076746; called by muse, mutect2, varscan2
- APLP2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.073); catalogued as COSV53845098; called by muse, mutect2, varscan2
- APOB | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51955374; called by muse, mutect2, varscan2
- APPL2 | c.1176G>C p.Q392H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV51594658; called by muse, mutect2, varscan2
- AQP9 | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV54971307; called by muse, mutect2, varscan2
- ARIH2 | c.877C>G p.H293D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV100711378, COSV62704520, COSV62706443, COSV62706552; called by muse, mutect2, varscan2
- ARIH2 | c.1204G>C p.G402R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62706557; called by muse, mutect2, varscan2
- ARMCX5 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs773138492, COSV55767821; called by muse, mutect2, varscan2
- ASB4 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57509161; called by muse, mutect2, varscan2
- ASTN1 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 37/171 reads (22%) | catalogued as COSV99923341; called by muse, mutect2, varscan2
- ATN1 | c.2851G>C p.E951Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63113281; called by muse, mutect2, varscan2
- ATP13A3 | c.3281G>T p.G1094V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55470030; called by muse, mutect2, varscan2
- ATP2B2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59508347; called by muse, mutect2, varscan2
- BAZ1B | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as COSV59995015; called by muse, mutect2
- BBS10 | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV67913447; called by muse, mutect2, varscan2
- BICDL2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs772074246, COSV101199482; called by muse, mutect2
- BICRA | c.3281C>T p.S1094F | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV67606493; called by muse, mutect2, varscan2
- BPIFC | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV55913203, COSV55916336; called by muse, mutect2, varscan2
- BRCA2 | c.8264G>C p.G2755A | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66463456; called by muse, mutect2, varscan2
- BUD23 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781981931, COSV56094883, COSV56096546; called by muse, mutect2, varscan2
- C18orf32 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV59088609; called by muse, mutect2, varscan2
- C3AR1 | c.959T>C p.L320S | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV50825730; called by muse, mutect2, varscan2
- C4orf3 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); catalogued as COSV67581702, COSV67582049; called by muse, mutect2, varscan2
- C5orf34 | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.767); catalogued as rs1226557257, COSV60929980, COSV60932259; called by muse, mutect2, varscan2
- C8A | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63486723; called by muse, mutect2, varscan2
- CACNA1D | c.3272del p.M1091Rfs*49 (on ENST00000350061 / NM_001128840.3; = p.M1111Rfs*49 on NM_000720.4) | Frame Shift Del (DEL) | VAF 28/108 reads (26%) | catalogued as COSV55466820; called by mutect2, pindel, varscan2
- CACNB1 | c.384C>G p.F128L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV60000561; called by muse, mutect2, varscan2
- CARS1 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1269419158, COSV53461688; called by muse, mutect2, varscan2
- CBLB | c.2308G>C p.D770H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.157); catalogued as COSV51438093; called by muse, mutect2, varscan2
- CCDC106 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV54401998, COSV54402849; called by muse, mutect2, varscan2
- CCDC14 | c.2182G>C p.E728Q (on ENST00000488653; = p.E680Q on NM_022757.5) | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV59948242; called by muse, mutect2
- CCDC159 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV52259014, COSV52262061; called by muse, mutect2
- CCDC191 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV55676919; called by muse, mutect2, varscan2
- CCDC87 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV59580752; called by muse, mutect2, varscan2
- CCDC88A | c.4775G>C p.R1592T (on ENST00000436346 / NM_001365480.1; = p.R1564T on NM_018084.5) | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55070860; called by muse, mutect2, varscan2
- CCDC88C | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV101106302, COSV99062317; called by muse, mutect2
- CCDC96 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV59509753; called by muse, mutect2, varscan2
- CD28 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60731716; called by muse, mutect2, varscan2
- CDH2 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV52276889; called by muse, mutect2, varscan2
- CEP250 | c.5404C>A p.Q1802K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.687); catalogued as COSV61175080; called by muse, mutect2, varscan2
- CEP63 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as rs749742427, COSV59679790; called by muse, mutect2, varscan2
- CEP72 | c.801G>C p.K267N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.08); catalogued as COSV53797483, COSV99375220; called by muse, mutect2, varscan2
- CHD5 | c.4913-2A>G p.X1638_splice | Splice Site (SNP) | VAF 32/100 reads (32%) | catalogued as COSV52426444; called by muse, mutect2, varscan2
- CHD7 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs371930390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.3253G>C p.E1085Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71115093; called by muse, mutect2, varscan2
- CIBAR1 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.596); catalogued as COSV99053440; called by muse, mutect2
- CLDN17 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV54524810; called by muse, mutect2, varscan2
- CLRN1 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as COSV58997431; called by muse, mutect2, varscan2
- CLSTN2 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.895); catalogued as rs555082751, COSV71718074, COSV71720623; called by muse, mutect2
- COL11A1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs995254814, COSV62175243; called by muse, mutect2, varscan2
- COL15A1 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.108); catalogued as rs778700512, COSV66649921; called by muse, mutect2, varscan2
- COL1A2 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs765271962, COSV51958062, COSV51959307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL25A1 | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV67659963; called by muse, mutect2, varscan2
- CREB3L2 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV57800770; called by muse, mutect2, varscan2
- CTBP1 | c.816G>C p.E272D | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as rs1350826314, COSV99338219; called by muse, mutect2, varscan2
- CWC15 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99688648; called by muse, mutect2
- CWC27 | c.1094A>G p.Q365R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1246644399, COSV66889089; called by muse, mutect2, varscan2
- CYP11B2 | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV59998111; called by muse, mutect2, varscan2
- CYP3A4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV60504480; called by muse, mutect2
- CYP3A43 | c.747A>T p.L249F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs767952577, COSV55938439; called by muse, mutect2, varscan2
- DDX41 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV57902475, COSV57905825; called by muse, mutect2, varscan2
- DDX58 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV65882010, COSV65885052; called by muse, mutect2, varscan2
- DENND4B | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.452); catalogued as COSV57844459; called by muse, mutect2, varscan2
- DKK3 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58870714; called by muse, mutect2, varscan2
- DLG1 | c.2024G>A p.G675E | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV58392467; called by muse, mutect2
- DMTF1 | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV58688695; called by muse, mutect2, varscan2
- DMTF1 | c.2047A>G p.I683V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs990301876, COSV57539166; called by muse, mutect2, varscan2
- DNAH11 | c.4633C>G p.H1545D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV60969618, COSV60985006; called by muse, mutect2
- DNAH17 | c.4724G>A p.R1575K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1220695530, COSV67751628, COSV67761955; called by muse, mutect2, varscan2
- DOCK9 | c.2238G>C p.K746N (on ENST00000376460 / NM_001366676.2; = p.K747N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV59645586; called by muse, mutect2, varscan2
- DOP1B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1285756369, COSV54281937; called by muse, mutect2, varscan2
- DPPA2 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72118355; called by muse, mutect2, varscan2
- DRP2 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as COSV100872082; called by muse, mutect2
- DVL1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1167067444, COSV66678582; called by muse, mutect2, varscan2
- DXO | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV61714858, COSV61715269; called by muse, mutect2, varscan2
- EAF2 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV56546322; called by muse, mutect2
- EGFR | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV51816076; called by muse, mutect2, varscan2
- EHF | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.671); catalogued as COSV57670280; called by muse, mutect2, varscan2
- EIF4A3 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV53921702; called by muse, mutect2, varscan2
- ELF3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs1196292458, COSV62840610; called by muse, mutect2, varscan2
- EPC2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99310277; called by muse, mutect2, varscan2
- EPHA2 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV64454942; called by muse, mutect2, varscan2
- EPHB4 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV100639684; called by muse, mutect2
- EPS8 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99843789; called by muse, mutect2, varscan2
- EPX | c.1024C>G p.Q342E | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV56599672; called by muse, mutect2, varscan2
- ESRRG | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63183421; called by muse, mutect2, varscan2
- ESYT1 | c.2584G>T p.E862* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99920375; called by muse, mutect2, varscan2
- ETAA1 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55475436; called by muse, varscan2
- ETV5 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60503551, COSV60507165; called by muse, mutect2, varscan2
- EXOC7 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.225); catalogued as COSV58745264; called by muse, mutect2, varscan2
- EXOC8 | c.95C>G p.S32W | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV50480113; called by muse, mutect2, varscan2
- F5 | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs1015942089, COSV63123396, COSV63129047; called by muse, mutect2, varscan2
- FAN1 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV62952345; called by muse, mutect2, varscan2
- FAR1 | c.455C>G p.S152* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100701675, COSV61384049; called by muse, mutect2, varscan2
- FAR1 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.081); catalogued as COSV61386712; called by muse, mutect2, varscan2
- FASN | c.7285G>A p.A2429T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as COSV60761936; called by muse, mutect2, varscan2
- FBXO42 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV65047187; called by muse, mutect2, varscan2
- FKBP9 | c.810C>G p.N270K | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.028); catalogued as COSV54235377; called by muse, mutect2, varscan2
- FOXD4L1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99380886; called by mutect2, varscan2
- FRMPD1 | c.2380G>C p.E794Q | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV100899607, COSV66703545; called by muse, mutect2, varscan2
- FURIN | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51579479; called by muse, mutect2
- FUT2 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV67179840; called by muse, mutect2, varscan2
- FUT3 | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV54608970; called by muse, mutect2, varscan2
- GAL3ST4 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57586472, COSV57588433; called by muse, mutect2, varscan2
- GART | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.303); catalogued as rs372112153; called by muse, mutect2, varscan2
- GCSAML | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1427262828, COSV63577953, COSV63579783; called by muse, mutect2, varscan2
- GFI1 | c.1080C>G p.F360L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs373356460; called by muse, mutect2, varscan2
- GJA9 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV62532933; called by muse, mutect2, varscan2
- GLT8D1 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV56478879; called by muse, mutect2, varscan2
- GNA13 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV71474364, COSV71474492; called by muse, mutect2, varscan2
- GNPTAB | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68450014; called by muse, varscan2
- GRK5 | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as rs1265496637, COSV100963300; called by muse, mutect2, varscan2
- HACD4 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.903); catalogued as COSV72217491, COSV72217738; called by muse, mutect2, varscan2
- HAP1 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.954); catalogued as COSV57881075; called by muse, mutect2, varscan2
- HERC2 | c.3595C>T p.Q1199* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99877327; called by muse, mutect2, varscan2
- HK2 | c.26A>T p.Y9F | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs768264746, COSV51880181; called by muse, mutect2, varscan2
- HMCN1 | c.16130C>T p.P5377L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV54945990, COSV99624948; called by muse, mutect2, varscan2
- HNRNPLL | c.803-1G>C p.X268_splice | Splice Site (SNP) | VAF 11/81 reads (14%) | catalogued as COSV55369613, COSV99696606; called by muse, mutect2, varscan2
- HSPA1L | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV65149547; called by muse, mutect2, varscan2
- HSPA9 | c.870C>G p.F290L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51866473; called by muse, mutect2, varscan2
- HYDIN | c.7381G>A p.E2461K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV99993863; called by muse, mutect2, varscan2
- IFIT1 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs747902583, COSV65661408; called by muse, mutect2, varscan2
- ITGAM | c.3132C>G p.F1044L (on ENST00000648685 / NM_001145808.2; = p.F1043L on NM_000632.4) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs756051605, COSV54936105; called by muse, mutect2, varscan2
- ITPR1 | c.7532G>A p.R2511K (on ENST00000354582; = p.R2456K on NM_002222.7) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV57004771; called by muse, mutect2, varscan2
- JAK2 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV67682809; called by muse, mutect2, varscan2
- KDM2B | c.2464C>G p.Q822E | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs1555289270, COSV65645662; called by muse, mutect2, varscan2
- KHDC4 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.28); catalogued as COSV64165015; called by muse, mutect2, varscan2
- KIF13A | c.4603G>T p.E1535* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99438553; called by muse, mutect2, varscan2
- KIF23 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.354); catalogued as COSV52983309; called by muse, mutect2, varscan2
- KIF2C | c.1534G>C p.E512Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64765769; called by muse, mutect2, varscan2
- KIF6 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as COSV54667453, COSV54696967; called by muse, mutect2, varscan2
- KLF17 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as rs771825513, COSV64856358; called by muse, mutect2, varscan2
- KLHL12 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.966); catalogued as COSV66126695; called by muse, mutect2, varscan2
- KLHL23 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55870034; called by muse, mutect2, varscan2
- KLHL28 | c.808C>G p.H270D | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.099); catalogued as rs374030406; called by muse, mutect2, varscan2
- KLHL35 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.32); catalogued as COSV66219498, COSV66219637; called by muse, mutect2, varscan2
- KMT2C | c.5851G>C p.D1951H | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51509473; called by muse, mutect2, varscan2
- KRT15 | c.471C>G p.F157L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99563332; called by muse, mutect2, varscan2
- KRT84 | c.184T>A p.S62T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57774001; called by muse, mutect2, varscan2
- LAP3 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs752655007, COSV56898176; called by muse, mutect2, varscan2
- LDLRAD1 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.246); catalogued as COSV64956396; called by muse, varscan2
- LGR4 | c.2574C>A p.C858* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100156721, COSV58727149; called by muse, mutect2, varscan2
- LIMCH1 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58298673; called by muse, mutect2, varscan2
- LRBA | c.4507C>T p.L1503F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV63966302; called by muse, mutect2, varscan2
- LTBP1 | c.3577C>T p.Q1193* (on ENST00000404816 / NM_206943.4; = p.Q867* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as COSV99698950; called by muse, mutect2, varscan2
- LYG2 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60716786; called by muse, mutect2, varscan2
- MAGEA3 | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 61/89 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV64756605; called by muse, mutect2, varscan2
- MARF1 | c.895C>G p.Q299E | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60029968; called by muse, mutect2, varscan2
- MIDEAS | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV54099584; called by muse, mutect2
- MIP | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs774928445, COSV57513130, COSV57514644; called by muse, mutect2, varscan2
- MORC1 | c.2743G>C p.D915H | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV51719800, COSV51732735; called by muse, mutect2, varscan2
- MRPL17 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV56619105, COSV99996925; called by muse, mutect2, varscan2
- MRPL35 | c.48C>G p.I16M | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV54493021, COSV54494288; called by muse, mutect2, varscan2
- MSH2 | c.2208C>G p.L736= | Splice Region (SNP) | VAF 15/95 reads (16%) | catalogued as COSV51885617; called by muse, mutect2, varscan2
- MTBP | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59966844; called by muse, mutect2, varscan2
- MTFR1 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.729); catalogued as rs1045523269, COSV50952921; called by muse, mutect2, varscan2
- MUC6 | c.3964C>G p.Q1322E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV70151051; called by muse, mutect2, varscan2
- MYH7B | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs762719894, COSV53426199; called by muse, mutect2, varscan2
- MYO1B | c.1931G>C p.R644T | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58438869; called by muse, mutect2, varscan2
- MYRIP | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV56883552; called by muse, mutect2, varscan2
- NCAPD2 | c.2126C>A p.A709D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV59703069; called by muse, mutect2, varscan2
- NLRP5 | c.2192C>T p.P731L | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs771877943, COSV66767819; called by muse, mutect2, varscan2
- NME6 | c.204C>G p.F68L (on ENST00000415053; = p.F76L on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV56641127; called by muse, mutect2, varscan2
- NPS | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV67690995; called by muse, mutect2, varscan2
- NRDC | c.1803G>C p.Q601H | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773408623, COSV100703394, COSV61409456; called by muse, mutect2, varscan2
- NRDE2 | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as rs922228851, COSV62964899; called by muse, mutect2
- NRXN1 | c.1671del p.S558Qfs*4 | Frame Shift Del (DEL) | VAF 27/117 reads (23%) | catalogued as COSV58495137; called by mutect2, pindel, varscan2
- NSUN7 | c.956C>G p.S319* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as rs1197523154, COSV57275033; called by muse, varscan2
- NUDT16L1 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52154965; called by muse, mutect2, varscan2
- NUMA1 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV61191737; called by muse, mutect2, varscan2
- NUP155 | c.424G>A p.E142K (on ENST00000231498 / NM_153485.3; = p.E83K on NM_004298.4) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51529738; called by muse, mutect2, varscan2
- NUP160 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65856314; called by muse, mutect2, varscan2
- NUTM1 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61548638; called by muse, mutect2, varscan2
- NUTM1 | c.3132_3134del p.G1045del | In Frame Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs1377032269; called by pindel, varscan2
- OBSCN | c.12554C>G p.A4185G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV52836701; called by mutect2, varscan2
- OBSCN | c.15963C>G p.I5321M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99485220; called by muse, mutect2
- OR1G1 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV61030717; called by muse, varscan2
- OR1G1 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV61030724; called by muse, varscan2
- OR4N2 | c.727C>A p.H243N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs754767564, COSV100269341, COSV60055457; called by muse, mutect2, varscan2
- OR6K3 | c.823T>G p.L275V (on ENST00000368146; = p.L259V on NM_001005327.2) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.993); catalogued as COSV63745754, COSV63746082; called by muse, mutect2, varscan2
- PAN2 | c.719C>G p.S240* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV57752730, COSV99228552; called by muse, mutect2, varscan2
- PAN2 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.194); catalogued as COSV57756381; called by muse, mutect2, varscan2
- PAN2 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs771473187, COSV57756389; called by muse, varscan2
- PATJ | c.5032G>C p.E1678Q | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV64507079; called by muse, mutect2, varscan2
- PCDH15 | c.4982C>T p.T1661I (on ENST00000644397 / NM_001354429.2; = p.T1603I on NM_001142771.2) | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.343); catalogued as COSV64744222; called by muse, mutect2, varscan2
- PCDH9 | c.2127G>A p.M709I | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.173); catalogued as COSV60535122, COSV60578608; called by muse, mutect2
- PDE11A | c.1362G>C p.E454D | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs769017439, COSV53692655; called by muse, mutect2, varscan2
- PDE4A | c.2175G>C p.Q725H (on ENST00000380702 / NM_001111307.2; = p.Q486H on NM_006202.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.087); catalogued as COSV53363589; called by muse, mutect2, varscan2
- PDE4DIP | c.4148C>G p.S1383* | Nonsense Mutation (SNP) | VAF 22/218 reads (10%) | catalogued as COSV100519774, COSV57718114; called by muse, mutect2, varscan2
- PDZD2 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56874612; called by muse, mutect2, varscan2
- PGBD1 | c.1333C>G p.Q445E | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV52556368; called by muse, mutect2, varscan2
- PHGDH | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as CM149801, COSV65572768; called by muse, mutect2, varscan2
- PHLDB2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV67316541; called by muse, mutect2, varscan2
- PI3 | c.258G>C p.L86F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.223); catalogued as COSV54783908; called by muse, mutect2, varscan2
- PIAS1 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99987184; called by muse, mutect2, varscan2
- PIGR | c.2118G>C p.E706D | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV62905189; called by muse, mutect2, varscan2
- PIK3C2B | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs992800920, COSV65810569; called by muse, varscan2
- PLCL1 | c.3156G>T p.M1052I | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV70826986, COSV70878934; called by muse, mutect2, varscan2
- PLEKHG4B | c.2534G>A p.R845Q (on ENST00000283426; = p.R1201Q on NM_052909.5) | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148185735, COSV52043673; called by muse, mutect2, varscan2
- PLS1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV61835687; called by muse, varscan2
- PLXNA3 | c.3794C>G p.S1265C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs781937905, COSV63755962; called by muse, mutect2, varscan2
- PNISR | c.704G>C p.W235S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65080926; called by muse, mutect2, varscan2
- POP1 | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs368501096, COSV62894286; called by muse, mutect2, varscan2
- PPP1R8 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as COSV99361138; called by muse, varscan2
- PRKRA | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV57870876; called by muse, mutect2, varscan2
- QSER1 | c.2714C>G p.S905C (on ENST00000399302; = p.S1034C on NM_001076786.3) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV67901930; called by muse, mutect2, varscan2
- RAD51B | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV66856035; called by muse, mutect2, varscan2
- RBM15 | c.974G>C p.R325P | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63924613; called by muse, varscan2
- RBM15 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV63923497, COSV63924617; called by muse, varscan2
- RBM23 | c.1314C>T p.T438= (on ENST00000359890 / NM_001077351.2; = p.T422= on NM_018107.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 30/123 reads (24%) | catalogued as COSV57127200, COSV57129089; called by muse, mutect2, varscan2
- RGS22 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1230189102, COSV62668439; called by muse, mutect2, varscan2
- RPGRIP1L | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100046930; called by muse, mutect2
- RPS6KA6 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV53127636; called by muse, mutect2, varscan2
- RRP1B | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV61480728; called by muse, mutect2, varscan2
- RSL1D1 | c.519C>G p.F173L | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451666326, COSV100851983, COSV63078615; called by muse, mutect2, varscan2
- RTEL1 | c.2907C>G p.I969M | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.156); catalogued as rs1413866305, COSV58893040, COSV58902492; called by muse, mutect2, varscan2
- RUBCN | c.1358-1G>A p.X453_splice | Splice Site (SNP) | VAF 19/140 reads (14%) | catalogued as COSV56375347; called by muse, mutect2, varscan2
- RYR1 | c.14029G>C p.E4677Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV62112524; called by muse, varscan2
- RYR2 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV63718327; called by muse, mutect2, varscan2
- SACS | c.10999C>T p.H3667Y | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV66535511; called by muse, mutect2, varscan2
- SATB1 | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1266168264, COSV58673191; called by muse, mutect2, varscan2
- SIGLEC5 | c.1371C>G p.I457M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV55784533; called by muse, mutect2, varscan2
- SIM1 | c.348+2T>A p.X116_splice | Splice Site (SNP) | VAF 36/132 reads (27%) | catalogued as rs1404367308, COSV53497401; called by muse, mutect2, varscan2
- SIRPB1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV53541212; called by muse, mutect2
- SLC22A12 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.243); catalogued as COSV60574335; called by muse, mutect2, varscan2
- SLC6A9 | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.981); catalogued as COSV62212361; called by muse, mutect2, varscan2
- SLC9A4 | c.753G>C p.K251N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV54839972; called by muse, mutect2
- SLIT2 | c.4342G>C p.D1448H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99887821; called by muse, mutect2
- SLITRK3 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV53847277, COSV99580297; called by muse, mutect2
- SMCHD1 | c.3578C>G p.S1193C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV55270063; called by muse, mutect2, varscan2
- SMYD1 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV101352467, COSV70226181; called by muse, mutect2, varscan2
- SNCAIP | c.1386C>A p.H462Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54422842; called by muse, mutect2, varscan2
- SOBP | c.308C>G p.S103* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as COSV100433469; called by muse, mutect2, varscan2
- SPAG9 | c.2623G>T p.E875* (on ENST00000262013 / NM_001130528.3; = p.E861* on NM_003971.6) | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100006132; called by muse, mutect2, varscan2
- SPATA31D1 | c.1178A>T p.H393L | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV61202022; called by muse, mutect2, varscan2
- SPTA1 | c.3507G>C p.Q1169H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV63760625; called by muse, mutect2, varscan2
- SPTBN4 | c.2949G>A p.M983I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as rs765568459, COSV58960170; called by muse, mutect2, varscan2
- SRCAP | c.6275C>G p.S2092C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1326223440, COSV52682109; called by muse, mutect2, varscan2
- SRP72 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1200171788, COSV100714227, COSV61377723, COSV61379468; called by muse, mutect2, varscan2
- ST13 | c.101G>T p.W34L | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV53422905; called by muse, mutect2, varscan2
- SV2C | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as COSV59216325, COSV59230261; called by muse, mutect2, varscan2
- SYNPO2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1193047091, COSV61118585; called by muse, mutect2, varscan2
- SYPL2 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV63995394; called by muse, mutect2, varscan2
- TARBP1 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs1244645389, COSV50209293; called by muse, mutect2, varscan2
- TAS2R16 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.04); catalogued as COSV50796983, COSV50797350, COSV50798214; called by muse, mutect2, varscan2
- TBL1XR1 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV61793132; called by muse, mutect2, varscan2
- TECRL | c.308G>C p.R103P | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67091054; called by muse, mutect2, varscan2
- TEX14 | c.1798C>G p.Q600E (on ENST00000240361 / NM_001201457.2; = p.Q594E on NM_031272.5) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as COSV53627826; called by muse, mutect2, varscan2
- TICRR | c.2392C>G p.Q798E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.066); catalogued as rs752762474, COSV51547829; called by muse, mutect2, varscan2
- TMEFF2 | c.314C>A p.S105Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55841870; called by muse, mutect2, varscan2
- TMEM169 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.858); catalogued as rs778515573, COSV55264302; called by mutect2, varscan2
- TMEM190 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.271); catalogued as rs772541050, COSV52582546; called by muse, mutect2, varscan2
- TMEM59 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV52376210; called by muse, mutect2, varscan2
- TMPO | c.475_477del p.S159del | In Frame Del (DEL) | VAF 4/44 reads (9%) | catalogued as rs754290044; called by pindel, varscan2
- TMX3 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1489553731, COSV55188316; called by muse, mutect2
- TNFAIP8L2 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV64423647; called by muse, mutect2, varscan2
- TNPO3 | c.2689G>A p.D897N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV55287739; called by muse, mutect2, varscan2
- TOMM70 | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52525988; called by muse, mutect2, varscan2
- TP73 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV60706621; called by muse, mutect2, varscan2
- TPH2 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 34/119 reads (29%) | catalogued as COSV100422439; called by muse, mutect2, varscan2
- TPR | c.2303G>C p.R768T | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV100824249, COSV66605501; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1460C>G p.S487* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100935942; called by muse, mutect2, varscan2
- TRIP11 | c.2074C>G p.Q692E | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV50967765; called by muse, mutect2, varscan2
- TRIP11 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV50967915; called by muse, mutect2, varscan2
- TRPM8 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.091); catalogued as rs201115161, COSV61221816; called by muse, mutect2, varscan2
- TTC17 | c.510A>G p.I170M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.812); catalogued as COSV50022841; called by muse, mutect2, varscan2
- TTI1 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.399); catalogued as rs1258331132, COSV65061244; called by muse, mutect2, varscan2
- TTN | c.81301C>A p.P27101T (on ENST00000591111; = p.P19677T on NM_003319.4) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | PolyPhen benign (0.143); catalogued as COSV60385366; called by muse, mutect2, varscan2
- TTN | c.23936C>G p.S7979C (on ENST00000591111; = p.S7052C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | PolyPhen benign (0.391); catalogued as rs375076623; called by muse, mutect2, varscan2
- TXLNA | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.081); catalogued as COSV65315287; called by muse, mutect2
- UGT2A1 | c.958A>G p.N320D | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV54147113; called by muse, mutect2, varscan2
- UHRF2 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV52796605; called by muse, mutect2, varscan2
- USP1 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as COSV100375495, COSV104411717; called by mutect2, varscan2
- USP17L2 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100414787; called by mutect2, varscan2
- USP33 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as COSV62471721; called by muse, mutect2, varscan2
- USP34 | c.7342G>A p.E2448K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1182194790, COSV68398498; called by muse, mutect2, varscan2
- UTP14A | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.129); catalogued as COSV64087965; called by muse, mutect2, varscan2
- VANGL1 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59622665; called by muse, mutect2, varscan2
- VAT1L | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV56815264, COSV56815893; called by muse, mutect2, varscan2
- VPS13C | c.5110C>G p.Q1704E (on ENST00000644861 / NM_020821.3; = p.Q1661E on NM_017684.5) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.1); catalogued as COSV51427682, COSV99827376; called by muse, mutect2, varscan2
- VPS28 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs75776765, COSV52873804; called by muse, mutect2, varscan2
- VTN | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV56875148; called by muse, mutect2, varscan2
- WDHD1 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as rs554232187; called by mutect2, varscan2
- XIRP2 | c.8899T>C p.S2967P (on ENST00000628543; = p.S3142P on NM_152381.6) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54737991; called by muse, mutect2, varscan2
- ZC3H13 | c.930G>C p.K310N | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54464713; called by muse, mutect2, varscan2
- ZFYVE28 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV52118221; called by muse, mutect2, varscan2
- ZFYVE9 | c.2812G>A p.D938N | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV55101216; called by muse, mutect2, varscan2
- ZNF114 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.026); catalogued as COSV59945391; called by muse, mutect2, varscan2
- ZNF160 | c.2242C>A p.L748M | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200114429, COSV62001172; called by muse, mutect2, varscan2
- ZNF208 | c.1936T>A p.F646I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV68113462; called by muse, varscan2
- ZNF320 | c.1382G>C p.R461T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV67087970, COSV67089106; called by muse, varscan2
- ZNF320 | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV67087745, COSV67089111; called by muse, varscan2
- ZNF407 | c.2825C>G p.S942* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99996965; called by muse, mutect2, varscan2
- ZNF446 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as COSV59992280; called by muse, mutect2
- ZNF527 | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV62236139; called by muse, mutect2, varscan2
- ZNF540 | c.702G>C p.Q234H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as COSV57108389, COSV57110045; called by muse, mutect2, varscan2
- ZNF546 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs916796046, COSV61259717; called by muse, mutect2, varscan2
- ZNF799 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); catalogued as COSV101345303; called by muse, varscan2
- ZNF80 | c.612C>G p.F204L | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV57362786; called by muse, mutect2, varscan2
- ZP4 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV63913684, COSV99053314; called by muse, mutect2, varscan2
- ZSCAN18 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53737893; called by muse, mutect2, varscan2
- ZSWIM5 | c.866C>A p.T289K | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV62737432; called by muse, mutect2, varscan2
- ANKFY1 | c.1775_1776del p.V592Afs*25 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by pindel, varscan2
- CLPTM1 | c.1222_1224del p.L408del | In Frame Del (DEL) | VAF 23/190 reads (12%) | called by pindel, varscan2
- COPS2 | c.982_983del p.K328Dfs*12 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- GRIN3A | c.2135_2136del p.K712Sfs*59 | Frame Shift Del (DEL) | VAF 30/134 reads (22%) | called by mutect2, pindel, varscan2
- KCTD21 | c.774del p.Y259Tfs*40 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, pindel, varscan2
- MAP3K20 | c.1985del p.G662Afs*170 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- NIBAN2 | c.1499_1501del p.S500del | In Frame Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel, varscan2
- NLRP7 | c.2871_2873del p.K957del (on ENST00000340844 / NM_206828.3; = p.K986del on NM_139176.3) | In Frame Del (DEL) | VAF 38/132 reads (29%) | called by mutect2, pindel, varscan2
- PGD | c.877_878del p.L293Efs*3 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by pindel, varscan2*
- PRAMEF4 | c.857A>G p.H286R | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC27A2 | c.236_237del p.L79Hfs*34 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by pindel, varscan2
- SPATA31A1 | c.2012T>G p.L671R | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYTL1 | c.1597_1599del p.E533del (on ENST00000543823; = p.E521del on NM_032872.3) | In Frame Del (DEL) | VAF 11/39 reads (28%) | called by pindel, varscan2
- WDHD1 | c.688dup p.S230Ffs*20 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13833C>G p.V4611= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV101291454; called by muse, mutect2
- ACTB | c.213C>T p.I71= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs752744378, COSV59320719, COSV59321626; called by muse, mutect2, varscan2
- ADIPOR2 | c.906C>T p.F302= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV63947845; called by muse, varscan2
- ADIPOR2 | c.960C>G p.L320= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV63947851; called by muse, varscan2
- ADORA2A | c.646C>T p.L216= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV58378880; called by muse, mutect2, varscan2
- AHNAK2 | c.11553C>A p.L3851= | Silent (SNP) | VAF 61/195 reads (31%) | catalogued as COSV60932683; called by muse, mutect2, varscan2
- AL592490.1 | c.597C>T p.I199= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs1016172171, COSV69428248; called by muse, mutect2, varscan2
- ANKRD11 | c.1479G>A p.R493= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV56373417; called by muse, mutect2, varscan2
- ANKRD20A1 | c.2034C>T p.F678= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs1181352528; called by mutect2, varscan2
- ARID3A | c.1191C>T p.I397= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV55044982; called by muse, mutect2
- B4GALT4 | c.1020C>T p.F340= | Silent (SNP) | VAF 11/140 reads (8%) | catalogued as COSV63296521; called by muse, mutect2
- BAIAP2 | c.363G>A p.K121= | Silent (SNP) | VAF 22/147 reads (15%) | catalogued as COSV58334057, COSV58341242; called by muse, mutect2, varscan2
- BRINP2 | c.1125G>A p.L375= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as COSV64179507, COSV64180738; called by muse, mutect2, varscan2
- C11orf53 | c.579C>T p.S193= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs373012938; called by muse, mutect2, varscan2
- CD4 | c.228G>A p.L76= | Silent (SNP) | VAF 27/157 reads (17%) | catalogued as COSV50596877; called by muse, mutect2, varscan2
- CENPL | c.285C>G p.L95= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as COSV100616367, COSV61893101; called by muse, mutect2, varscan2
- CR1 | c.3783C>T p.F1261= | Silent (SNP) | VAF 52/211 reads (25%) | catalogued as rs1188706782, COSV65460427, COSV65464367; called by muse, varscan2
- CROCC | c.4422C>T p.L1474= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs373265072; called by mutect2, varscan2
- CUL2 | c.519A>T p.G173= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs772715222, COSV66081411; called by muse, mutect2, varscan2
- CYP26B1 | c.810C>T p.L270= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99135144; called by muse, mutect2
- CYP4A22 | c.1146C>G p.L382= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV53742762; called by muse, mutect2, varscan2
- DENND1A | c.1089C>T p.L363= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV101010822; called by muse, mutect2
- DOK1 | c.1416G>A p.K472= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV51215718; called by muse, mutect2, varscan2
- EDC4 | c.3294C>T p.I1098= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs756406919, COSV59304077; called by muse, mutect2, varscan2
- FHL2 | c.423C>T p.F141= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as COSV59080686; called by muse, mutect2, varscan2
- FICD | c.90G>A p.L30= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs745482581, COSV64202373; called by muse, mutect2, varscan2
- FLG | c.5196G>A p.Q1732= | Silent (SNP) | VAF 50/265 reads (19%) | catalogued as COSV64250994; called by muse, mutect2, varscan2
- FLNB | c.6054C>T p.F2018= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs199857882, COSV55870547; called by muse, mutect2, varscan2
- FLRT2 | c.243T>C p.P81= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV58151261; called by muse, mutect2, varscan2
- FREM2 | c.1071C>T p.F357= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV54841851; called by muse, mutect2, varscan2
- FRMPD1 | c.343C>A p.R115= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV63384024, COSV63384031; called by muse, mutect2, varscan2
- GAD2 | c.696G>A p.G232= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV52169793; called by muse, mutect2, varscan2
- GLI2 | c.357C>T p.H119= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs755546542, COSV58052426; called by muse, mutect2, varscan2
- GNPDA1 | c.756C>A p.V252= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV60943296; called by muse, mutect2, varscan2
- GOSR1 | c.75G>A p.L25= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs1335964550, COSV56718916, COSV56721131; called by muse, mutect2, varscan2
- GRK6 | c.870C>T p.F290= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV62684549; called by muse, mutect2, varscan2
- HAP1 | c.498C>T p.V166= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs1555591463, COSV57881094; called by muse, varscan2
- HEXD | c.333C>T p.F111= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV60066352; called by muse, mutect2, varscan2
- HIC2 | c.144C>A p.V48= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV68042780, COSV68042976; called by muse, mutect2, varscan2
- HYOU1 | c.2475C>T p.L825= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs200889803; called by muse, mutect2, varscan2
- IGDCC3 | c.330G>A p.S110= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs769811625, COSV60080668; called by muse, mutect2, varscan2
- ITPKA | c.924C>T p.R308= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV53028157; called by muse, mutect2
- JMJD6 | c.651C>G p.L217= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV57974167, COSV57976186; called by muse, mutect2, varscan2
- LAMA2 | c.1131C>T p.V377= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV69001126; called by muse, mutect2, varscan2
- LDLRAD1 | c.525C>T p.F175= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV64956403; called by muse, varscan2
- LEFTY2 | c.726C>G p.L242= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV64747830; called by muse, varscan2
- LHFPL2 | c.36C>T p.L12= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100982692, COSV66714678; called by muse, mutect2, varscan2
- LILRB1 | c.1563A>G p.L521= (on ENST00000427581; = p.L471= on NM_006669.6) | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV61122134; called by muse, mutect2, varscan2
- LPAR3 | c.510C>T p.L170= | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as COSV65455282; called by muse, mutect2, varscan2
- MAPRE2 | c.672C>G p.A224= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV55821903; called by muse, mutect2
- MSLN | c.1452C>G p.L484= (on ENST00000382862 / NM_013404.4; = p.L476= on NM_005823.6) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs371356000, COSV53506900; called by muse, mutect2, varscan2
- MTMR6 | c.1356G>A p.E452= | Silent (SNP) | VAF 56/257 reads (22%) | catalogued as COSV67809984; called by muse, mutect2, varscan2
- NAV3 | c.2493C>G p.L831= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV57115303; called by muse, mutect2, varscan2
- NLRP5 | c.132G>A p.L44= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as COSV66767817; called by muse, mutect2, varscan2
- NOTCH2 | c.513C>T p.L171= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV56708104; called by muse, mutect2
- NR4A2 | c.1281C>T p.F427= | Silent (SNP) | VAF 28/214 reads (13%) | catalogued as rs777699862, COSV59895893; called by muse, mutect2, varscan2
- NUP210 | c.3567C>T p.V1189= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV54414952; called by muse, mutect2, varscan2
- OR10J1 | c.12G>A p.E4= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV71129841; called by muse, mutect2, varscan2
- P3H1 | c.18G>A p.L6= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99355649; called by muse, mutect2
- PCDHA1 | c.699C>T p.L233= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1230076426, COSV65373715; called by muse, mutect2, varscan2
- PEX11B | c.588C>G p.L196= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs587729353, COSV100994749, COSV65199448; called by muse, mutect2, varscan2
- PGLS | c.474C>G p.L158= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV53113885; called by muse, mutect2, varscan2
- PKLR | c.534G>A p.V178= | Silent (SNP) | VAF 32/158 reads (20%) | catalogued as COSV61362679; called by muse, mutect2, varscan2
- PLCE1 | c.3387A>G p.Q1129= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV53374421; called by muse, varscan2
- PLD1 | c.1005C>G p.L335= | Silent (SNP) | VAF 49/197 reads (25%) | catalogued as COSV60574830; called by muse, mutect2, varscan2
- PLS1 | c.828G>A p.V276= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs768651130, COSV61835693; called by muse, varscan2
- PPP4R4 | c.1380C>T p.I460= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV58558924; called by muse, mutect2, varscan2
- PRUNE2 | c.8544G>A p.E2848= | Silent (SNP) | VAF 35/183 reads (19%) | catalogued as COSV56320594; called by muse, mutect2, varscan2
- PXDN | c.3849G>T p.R1283= | Silent (SNP) | VAF 84/144 reads (58%) | catalogued as COSV53247379; called by muse, mutect2, varscan2
- RAB34 | c.483C>G p.L161= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV56388934, COSV99973197; called by muse, mutect2, varscan2
- RAB9B | c.306G>A p.Q102= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV54588519; called by muse, mutect2, varscan2
- RNF148 | c.906C>T p.I302= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV57388601; called by muse, mutect2, varscan2
- RNF148 | c.732C>G p.L244= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100411797, COSV57364815; called by muse, mutect2
- RPL10A | c.516G>A p.V172= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV57691244; called by muse, mutect2, varscan2
- RTEL1 | c.3543C>A p.I1181= | Silent (SNP) | VAF 26/188 reads (14%) | catalogued as rs748910434, COSV53929420, COSV53929447; called by muse, mutect2, varscan2
- RYR2 | c.12792G>A p.L4264= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs749454470, COSV63718335; called by muse, varscan2
- SCAMP2 | c.387G>A p.V129= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV51513585; called by muse, mutect2, varscan2
- SDAD1 | c.1242C>G p.L414= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs772691754, COSV62403928; called by muse, mutect2, varscan2
- SEC16B | c.219A>G p.A73= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV57630586; called by muse, mutect2, varscan2
- SEC62 | c.750C>A p.L250= | Silent (SNP) | VAF 21/192 reads (11%) | catalogued as COSV61262343; called by muse, mutect2, varscan2
- SERPINA12 | c.987C>T p.S329= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100369762, COSV57946542; called by muse, mutect2, varscan2
- SLC26A9 | c.786C>T p.S262= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs752353578, COSV61605858; called by muse, mutect2, varscan2
- SRCAP | c.6165C>G p.L2055= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs145457424; called by muse, mutect2, varscan2
- SRCAP | c.6342C>T p.F2114= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV52682118; called by muse, mutect2, varscan2
- SSTR1 | c.582C>G p.V194= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV57457859; called by muse, mutect2, varscan2
- STAG3 | c.1038A>G p.K346= | Silent (SNP) | VAF 40/382 reads (10%) | catalogued as rs766666681, COSV100426223; called by muse, mutect2, varscan2
- STXBP1 | c.547C>T p.L183= | Silent (SNP) | VAF 47/66 reads (71%) | catalogued as rs753725349, COSV64815688; ClinVar: likely benign; called by muse, mutect2, varscan2
- THUMPD1 | c.774G>A p.L258= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV67263612; called by muse, mutect2, varscan2
- TMEFF2 | c.315C>A p.S105= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV55841856; called by muse, mutect2, varscan2
- TMPRSS4 | c.811C>T p.L271= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as COSV71110670; called by muse, mutect2, varscan2
- TOX4 | c.732G>A p.Q244= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as COSV52971589; called by muse, mutect2, varscan2
- TRAJ38 | c.51G>C p.L17= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, varscan2
- TRPM8 | c.3309C>T p.I1103= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV61224617; called by muse, mutect2, varscan2
- TRPV2 | c.1128G>A p.L376= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV58428578, COSV58431026; called by muse, mutect2, varscan2
- TXNDC16 | c.1182G>T p.V394= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as COSV55987972; called by muse, mutect2, varscan2
- USHBP1 | c.819C>T p.S273= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV53106471; called by muse, mutect2, varscan2
- VPS13B | c.6612G>A p.L2204= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV62159098; called by muse, mutect2, varscan2
- WIPF1 | c.864G>A p.Q288= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1052917202, COSV55820977; called by muse, mutect2, varscan2
- ZNF12 | c.2031C>T p.N677= (on ENST00000405858 / NM_016265.4; = p.N639= on NM_006956.3) | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as rs1420770334, COSV61245729; called by muse, mutect2
- ZNF236 | c.4191G>A p.Q1397= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV53499003; called by muse, mutect2, varscan2
- ZNF74 | c.1629C>T p.L543= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV62620681; called by muse, mutect2, varscan2
- ZSCAN2 | c.1533C>T p.F511= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as rs1488238603, COSV57572800; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-1003G>A | Intron (SNP) | VAF 23/72 reads (32%) | catalogued as COSV60824690; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2700G>A | Intron (SNP) | VAF 86/207 reads (42%) | catalogued as rs768178267, COSV56010933; called by muse, mutect2, varscan2
- DCAF13 | c.-29C>G | 5'UTR (SNP) | VAF 8/31 reads (26%) | catalogued as rs762435482, COSV52569558; called by muse, mutect2, varscan2
- HAP1 | c.549+21C>G | Intron (SNP) | VAF 20/76 reads (26%) | catalogued as rs782771295, COSV57881087; called by muse, varscan2
- SALL2 | c.*649C>T | 3'UTR (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100444635; called by muse, mutect2
- SNORD116-16 | n.42G>T | RNA (SNP) | VAF 54/320 reads (17%) | called by muse, mutect2, varscan2
- SPRTN | c.-1G>T | 5'UTR (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99150164; called by muse, varscan2
- SRPK1 | c.1691-314C>T | Intron (SNP) | VAF 19/102 reads (19%) | catalogued as COSV60414701; called by muse, mutect2, varscan2
- SV2A | c.-1C>T | 5'UTR (SNP) | VAF 20/99 reads (20%) | catalogued as rs782764818, COSV100975302; called by muse, mutect2, varscan2
